Somatic mutation profile of tumor specimen TCGA-2V-A95S-01A (aliquot TCGA-2V-A95S-01A-11D-A36X-10) from TCGA case TCGA-2V-A95S, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3.
Specimen TCGA-2V-A95S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c182da38-5fc7-4f3b-b401-54bc0b85c0d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2V-A95S-10D (Blood Derived Normal), aliquot TCGA-2V-A95S-10D-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8769b8-4ee8-4579-b5a2-c6db99784426

The open-access MAF lists 113 somatic variants for this specimen: 80 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 32, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 2, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV101186858; called by muse, mutect2, varscan2
- ADCY5 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs758401087, CM124569, COSV59197520; called by muse, mutect2, varscan2
- ALB | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as COSV99891253; called by muse, mutect2, varscan2
- ANKZF1 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55475341; called by muse, mutect2, varscan2
- ANO7 | c.377A>G p.Q126R (on ENST00000274979; = p.Q71R on NM_001001666.4) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs199644599; called by muse, mutect2, varscan2
- AP5Z1 | c.21G>C p.E7D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV100194991; called by muse, varscan2
- ATL2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs753260503, COSV60057818; called by mutect2, varscan2
- B4GALNT4 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV100327434; called by muse, mutect2
- BSN | c.11165A>G p.K3722R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as COSV99608092; called by muse, mutect2, varscan2
- CCDC150 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99776796; called by muse, mutect2, varscan2
- CEP112 | c.2608-2A>T p.X870_splice (on ENST00000392769 / NM_001353127.1; = p.X126_splice on NM_001037325.3) | Splice Site (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100439088; called by muse, mutect2, varscan2
- COL1A1 | c.4100C>T p.T1367I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99866998; called by muse, mutect2, varscan2
- COL4A1 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs1395505056, COSV101011086; called by muse, mutect2, varscan2
- COP1 | c.1734C>G p.H578Q | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58164301; called by muse, mutect2, varscan2
- CPNE1 | c.941A>G p.N314S (on ENST00000352393; = p.N319S on NM_003915.5) | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs138805916; called by muse, mutect2, varscan2
- CTNNAL1 | c.1180A>T p.K394* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100336474; called by muse, mutect2, varscan2
- DPP9 | c.2342A>G p.Y781C (on ENST00000598800; = p.Y810C on NM_139159.5) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376453990; called by muse, mutect2, varscan2
- EBF3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100798941, COSV62473667; called by muse, mutect2, varscan2
- EML5 | c.2792C>A p.S931Y | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV100714931; called by muse, mutect2, varscan2
- FAM135B | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1328882882, COSV99422544, COSV99422652; called by muse, mutect2, varscan2
- FAM222B | c.1239A>C p.E413D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV100368427; called by muse, mutect2, varscan2
- FAM47A | c.2209A>G p.I737V | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1214165078, COSV100649841; called by muse, mutect2, varscan2
- FCRL1 | c.1286T>C p.M429T | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1425178243, COSV100839766; called by muse, mutect2
- FCRL5 | c.1952G>T p.S651I | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV100708819; called by muse, mutect2, varscan2
- FHL3 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100885094; called by muse, mutect2, varscan2
- FMN2 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.044); catalogued as COSV100144587, COSV60443629; called by muse, mutect2, varscan2
- FNTA | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV100172486; called by muse, mutect2, varscan2
- GLG1 | c.1367A>T p.H456L | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as COSV99215654; called by muse, mutect2
- GNAI1 | c.1032A>G p.I344M | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as COSV100650464; called by muse, mutect2, varscan2
- GOLM1 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57414550, COSV99974316; called by muse, mutect2, varscan2
- GRM1 | c.3388G>T p.D1130Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV99265529; called by muse, mutect2, varscan2
- GSR | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99645513; called by muse, mutect2, varscan2
- H2BC14 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV100297561; called by muse, mutect2, varscan2
- KCNC2 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 214/648 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100128638, COSV100129973; called by muse, mutect2, varscan2
- KHDC4 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 89/587 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV100850792; called by muse, mutect2, varscan2
- KIF26B | c.1993A>G p.R665G | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.687); catalogued as rs1321001510, COSV100832138; called by muse, mutect2, varscan2
- LCE3E | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.312); catalogued as rs199901484; called by muse, mutect2, varscan2
- LPP | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.959); catalogued as COSV100446764, COSV57079770; called by muse, mutect2, varscan2
- MCTP2 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as COSV59149010; called by muse, mutect2, varscan2
- MMP28 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs765992640; called by muse, mutect2, varscan2
- MMRN1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs764060846, COSV99306965; called by muse, mutect2, varscan2
- MMS22L | c.1818C>A p.F606L | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV99246554; called by muse, mutect2, varscan2
- MYO1E | c.2086G>C p.D696H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.248); catalogued as COSV99895221; called by muse, mutect2, varscan2
- NCAPG2 | c.2291T>C p.I764T | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs995265100, COSV99316847; called by muse, mutect2, varscan2
- NEUROG1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100130776; called by muse, mutect2, varscan2
- NR1I3 | c.799G>C p.A267P (on ENST00000367982 / NM_001077480.3; = p.A263P on NM_005122.5) | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV100915616; called by muse, mutect2, varscan2
- OR1A1 | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV100410748; called by muse, mutect2, varscan2
- PDE11A | c.766A>T p.K256* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99611741; called by muse, mutect2, varscan2
- PDE1A | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100113888; called by muse, mutect2, varscan2
- PSMB5 | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV100557322; called by muse, mutect2, varscan2
- RNF17 | c.3630G>T p.M1210I | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV55047147, COSV99692903; called by muse, mutect2, varscan2
- ROBO1 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV101458581; called by muse, mutect2, varscan2
- RYR2 | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100769582; called by muse, mutect2, varscan2
- SALL1 | c.765G>T p.L255F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99173292; called by muse, mutect2, varscan2
- SCRN3 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV99767205; called by muse, mutect2, varscan2
- SDCCAG8 | c.1932A>C p.E644D | Missense Mutation (SNP) | VAF 151/818 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV100654125; called by muse, mutect2, varscan2
- SLC12A7 | c.3076G>A p.V1026I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs755398930, COSV53754819; called by muse, mutect2, varscan2
- SLC6A6 | c.231T>C p.G77= | Splice Region (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100692094; called by muse, mutect2, varscan2
- SMC2 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99658812; called by muse, mutect2, varscan2
- SOGA3 | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100846883; called by muse, varscan2
- SOS1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV101216821; called by muse, mutect2, varscan2
- STAT1 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100699983; called by muse, mutect2, varscan2
- SYT11 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100851300; called by muse, mutect2, varscan2
- TAF1L | c.2657A>G p.D886G | Missense Mutation (SNP) | VAF 74/409 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV99644514; called by muse, mutect2, varscan2
- TMEM215 | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 29/116 reads (25%) | catalogued as COSV100713167; called by muse, mutect2, varscan2
- TMPRSS6 | c.2353G>A p.G785S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776040622, COSV100695678; called by muse, mutect2, varscan2
- TRPT1 | c.457A>C p.I153L (on ENST00000317459 / NM_001160393.1; = p.I104L on NM_031472.4) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as COSV99655780; called by muse, mutect2, varscan2
- TSGA10IP | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs761245228, COSV101598401; called by muse, mutect2, varscan2
- TTN | c.27698T>A p.V9233E (on ENST00000591111; = p.V8306E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | PolyPhen benign (0.062); catalogued as COSV100606690; called by muse, mutect2, varscan2
- UBQLN4 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 14/148 reads (9%) | catalogued as COSV100849085; called by muse, mutect2
- USP29 | c.1622G>A p.C541Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54144724, COSV99517982; called by muse, mutect2, varscan2
- XPO5 | c.2255G>C p.G752A | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV99540763; called by muse, mutect2, varscan2
- ZC3H4 | c.1803-1G>C p.X601_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99452159; called by muse, mutect2, varscan2
- ZNF292 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370219, COSV60543821; called by muse, mutect2, varscan2
- ZNF836 | c.1640T>A p.I547N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100440840; called by muse, mutect2, varscan2
- ARID1A | c.5060del p.A1687Dfs*2 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- KCNT1 | c.2828_2831del p.L943Rfs*22 (on ENST00000488444; = p.L962Rfs*22 on NM_020822.3) | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel
- MAN2C1 | c.36_72del p.E15Pfs*23 | Frame Shift Del (DEL) | VAF 38/188 reads (20%) | called by mutect2, pindel
- ZBTB1 | c.569_577del p.F190_V192del | In Frame Del (DEL) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- ZC3H12A | c.595del p.L199Cfs*32 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- ADCY8 | c.2352C>A p.A784= | Silent (SNP) | VAF 59/346 reads (17%) | catalogued as COSV53923611, COSV53926136; called by muse, mutect2, varscan2
- CASP9 | c.1101G>T p.L367= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV61602332; called by muse, mutect2, varscan2
- DSC1 | c.1386T>A p.I462= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV99937532; called by muse, mutect2, varscan2
- EMSY | c.741C>T p.S247= | Silent (SNP) | VAF 27/201 reads (13%) | catalogued as rs1323017581, COSV100595615; called by muse, mutect2, varscan2
- EP300 | c.6456G>A p.Q2152= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV99608232; called by muse, mutect2, varscan2
- EPB41L5 | c.1923T>C p.S641= | Silent (SNP) | VAF 73/266 reads (27%) | catalogued as COSV99758564; called by muse, mutect2, varscan2
- F13A1 | c.882T>A p.T294= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV53555177, COSV99342753; called by muse, mutect2, varscan2
- FOXG1 | c.498G>A p.G166= | Silent (SNP) | VAF 68/315 reads (22%) | catalogued as COSV57397723; called by muse, mutect2
- FRG2C | c.762C>A p.A254= | Silent (SNP) | VAF 38/295 reads (13%) | called by muse, mutect2, varscan2
- GSAP | c.558A>G p.Q186= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99990105; called by muse, mutect2, varscan2
- IGFN1 | c.3249G>T p.A1083= (on ENST00000295591 / NM_001367841.1; = p.A3540= on NM_001164586.2) | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV55179979, COSV99811946; called by muse, mutect2, varscan2
- KIF26B | c.2565C>A p.S855= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV100832139; called by muse, mutect2
- LRIT2 | c.1203T>C p.D401= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100258764; called by muse, mutect2, varscan2
- MAGI2 | c.1068A>G p.K356= | Silent (SNP) | VAF 116/492 reads (24%) | catalogued as COSV100834127; called by muse, mutect2, varscan2
- MUC16 | c.23961C>A p.S7987= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV101199500; called by muse, mutect2, varscan2
- N4BP3 | c.936T>A p.A312= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99200656; called by muse, mutect2, varscan2
- OCRL | c.753C>A p.G251= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100843410; called by muse, mutect2, varscan2
- OR1E1 | c.888C>T p.D296= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as rs774514315, COSV100491915; called by muse, mutect2, varscan2
- OR2H1 | c.537C>T p.V179= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV101009836; called by muse, mutect2
- PCDH12 | c.3024C>T p.G1008= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99187411; called by muse, mutect2, varscan2
- PCDHB3 | c.639C>T p.T213= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs148121148, COSV99166615; called by muse, mutect2, varscan2
- SAA2 | c.306A>G p.K102= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV99879292; called by muse, mutect2, varscan2
- SH3D21 | c.2016C>T p.L672= (on ENST00000453908 / NM_001162530.2; = p.L561= on NM_024676.5) | Silent (SNP) | VAF 38/203 reads (19%) | catalogued as COSV99584014; called by muse, mutect2, varscan2
- SLC26A3 | c.387G>A p.P129= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs754233296, COSV60641088; called by muse, mutect2, varscan2
- STK10 | c.2906A>G p.*969= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99451296; called by muse, mutect2, varscan2
- TBX5 | c.1524T>G p.V508= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV100091051; called by muse, mutect2, varscan2
- TMPRSS6 | c.912G>A p.K304= | Silent (SNP) | VAF 67/270 reads (25%) | catalogued as rs1216581105, COSV100695681; called by muse, mutect2, varscan2
- TPO | c.1068C>T p.L356= | Silent (SNP) | VAF 199/865 reads (23%) | catalogued as COSV100220614; called by muse, mutect2, varscan2
- TRPS1 | c.2940A>G p.L980= (on ENST00000220888 / NM_001330599.2; = p.L993= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV99629980; called by muse, mutect2, varscan2
- TTN | c.43920C>T p.T14640= (on ENST00000591111; = p.T7216= on NM_003319.4) | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs547682223, COSV100600681; ClinVar: likely benign; called by muse, mutect2, varscan2
- UQCRQ | c.63G>T p.P21= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99737303; called by muse, varscan2
- ZSWIM8 | c.5490C>T p.L1830= (on ENST00000605216 / NM_001242487.2; = p.L1835= on NM_015037.3) | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs749096821, COSV100013864; called by muse, mutect2, varscan2
- SLC22A17 | n.1853C>T | RNA (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99248696; called by muse, mutect2, varscan2
